Somatic mutation profile of tumor specimen MP2PRT-PAVIZM-TMP1-A (aliquot MP2PRT-PAVIZM-TMP1-A-1-0-D-A83Q-36) from MP2PRT case MP2PRT-PAVIZM, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 8.0 years (2,937 days).
Specimen MP2PRT-PAVIZM-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bdc0d13d-cf89-4be7-b17f-bf3d646648fd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVIZM-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVIZM-NB1-A-1-0-D-A83Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/774f5f8d-8cda-4819-bb88-3a3620cd38d9

The open-access MAF lists 168 somatic variants for this specimen: 112 protein-altering or splice-affecting, 43 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 103, Silent 43, Nonsense Mutation 5, Intron 5, 3'UTR 3, 5'UTR 2, Frame Shift Ins 2, 3'Flank 2, Splice Site 1, In Frame Ins 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ETV6 | c.641C>T p.P214L | Missense Mutation (SNP) | VAF 205/540 reads (38%) | SIFT tolerated (0.26); PolyPhen benign (0.121); catalogued as rs724159947, CM150819, COSV67147991; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 63/286 reads (22%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 33/389 reads (8%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- ADAM18 | c.731C>A p.S244Y | Missense Mutation (SNP) | VAF 116/284 reads (41%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.976); catalogued as COSV55843435; called by muse, mutect2, varscan2
- AMER2 | c.100G>A p.A34T | Missense Mutation (SNP) | VAF 199/462 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); catalogued as rs199742395; called by muse, mutect2, varscan2
- ANK3 | c.3980C>T p.S1327F (on ENST00000280772 / NM_001320874.2; = p.S461F on NM_001149.3) | Missense Mutation (SNP) | VAF 89/234 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as COSV55063627, COSV99779039; called by muse, mutect2, varscan2
- ARHGEF16 | c.71G>A p.R24Q | Missense Mutation (SNP) | VAF 33/577 reads (6%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs1026294109; called by muse, mutect2
- CDH6 | c.967G>A p.E323K | Missense Mutation (SNP) | VAF 87/238 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as rs1211213609; called by muse, mutect2, varscan2
- CDON | c.2431C>T p.R811C | Missense Mutation (SNP) | VAF 103/280 reads (37%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as rs201985321, COSV55002416; called by muse, mutect2, varscan2
- CFAP46 | c.5992G>A p.E1998K | Missense Mutation (SNP) | VAF 177/459 reads (39%) | SIFT tolerated (0.45); PolyPhen benign (0.055); catalogued as rs375472359, COSV54155140; called by muse, mutect2, varscan2
- CFAP54 | c.2834G>A p.G945E | Missense Mutation (SNP) | VAF 83/258 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs866141518; called by muse, mutect2, varscan2
- CHI3L2 | c.518C>T p.S173F | Missense Mutation (SNP) | VAF 48/165 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as rs201086381; called by muse, mutect2, varscan2
- CIBAR1 | c.62C>T p.S21L | Missense Mutation (SNP) | VAF 88/247 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as rs1272626563; called by muse, mutect2, varscan2
- CIT | c.1184C>T p.S395L | Missense Mutation (SNP) | VAF 117/341 reads (34%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as rs752750796, COSV55869624; called by muse, mutect2, varscan2
- DLGAP2 | c.1001C>T p.P334L | Missense Mutation (SNP) | VAF 246/606 reads (41%) | SIFT tolerated (0.66); PolyPhen probably damaging (0.998); catalogued as rs1404079466, COSV70098229; called by muse, varscan2
- DSCAML1 | c.3623C>T p.T1208M (on ENST00000321322; = p.T1148M on NM_020693.4) | Missense Mutation (SNP) | VAF 156/381 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.039); catalogued as rs147519443; called by muse, mutect2, varscan2
- DST | c.19573C>T p.Q6525* (on ENST00000361203 / NM_001374722.1; = p.Q4222* on NM_015548.5) | Nonsense Mutation (SNP) | VAF 37/295 reads (13%) | catalogued as COSV55032209; called by muse, mutect2, varscan2
- ELMOD1 | c.97G>A p.G33R | Missense Mutation (SNP) | VAF 112/303 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.318); catalogued as COSV99759975; called by muse, mutect2, varscan2
- FHOD3 | c.3475G>A p.D1159N (on ENST00000359247 / NM_001281739.3; = p.D1176N on NM_025135.5) | Missense Mutation (SNP) | VAF 81/245 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.062); catalogued as rs773510270; called by muse, mutect2, varscan2
- GSG1L2 | c.694C>T p.R232C | Missense Mutation (SNP) | VAF 149/506 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as rs774753678, COSV101243943; called by muse, mutect2, varscan2
- GUCY1A1 | c.1375C>T p.P459S | Missense Mutation (SNP) | VAF 136/536 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56651341; called by muse, mutect2, varscan2
- LRP2 | c.12397G>A p.E4133K | Missense Mutation (SNP) | VAF 118/313 reads (38%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV55566677; called by muse, mutect2, varscan2
- MLXIPL | c.1984C>T p.R662C | Missense Mutation (SNP) | VAF 102/282 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782449502; called by muse, mutect2, varscan2
- MSANTD4 | c.497C>T p.S166F | Missense Mutation (SNP) | VAF 96/275 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.205); catalogued as rs765363080; called by muse, mutect2, varscan2
- MUC17 | c.5047T>C p.S1683P | Missense Mutation (SNP) | VAF 158/387 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); catalogued as rs201934879; called by muse, varscan2
- NMUR2 | c.1138C>T p.P380S | Missense Mutation (SNP) | VAF 103/322 reads (32%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.505); catalogued as rs771196482, COSV54923104; called by muse, mutect2, varscan2
- NRK | c.1837G>C p.E613Q | Missense Mutation (SNP) | VAF 76/629 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV99688347; called by muse, mutect2, varscan2
- NUGGC | c.1570G>A p.A524T | Missense Mutation (SNP) | VAF 105/302 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs751612628, COSV58435910, COSV58439665; called by muse, mutect2, varscan2
- OPRM1 | c.809C>T p.S270F | Missense Mutation (SNP) | VAF 139/537 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57672685; called by muse, mutect2, varscan2
- PRSS12 | c.179C>T p.P60L | Missense Mutation (SNP) | VAF 29/589 reads (5%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.001); catalogued as rs1398408462; called by muse, mutect2
- PTPRD | c.569G>A p.G190E | Missense Mutation (SNP) | VAF 81/228 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61960560; called by muse, mutect2, varscan2
- RASGRF1 | c.1196C>T p.T399M | Missense Mutation (SNP) | VAF 62/322 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs1234815073, COSV69181774; called by muse, mutect2, varscan2
- REG3A | c.262G>A p.V88M | Missense Mutation (SNP) | VAF 105/282 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.788); catalogued as rs764419758; called by muse, mutect2, varscan2
- RGPD3 | c.1640G>A p.G547E | Missense Mutation (SNP) | VAF 84/234 reads (36%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.887); catalogued as COSV58739660; called by muse, mutect2, varscan2
- RNF222 | c.289G>A p.V97M | Missense Mutation (SNP) | VAF 138/552 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.081); catalogued as rs1567711737; called by muse, mutect2, varscan2
- ROBO2 | c.790G>A p.D264N | Missense Mutation (SNP) | VAF 99/242 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); catalogued as COSV59922140; called by muse, mutect2, varscan2
- SAP130 | c.145A>G p.I49V | Missense Mutation (SNP) | VAF 94/239 reads (39%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.025); catalogued as rs911224695; called by muse, mutect2, varscan2
- SERPINA3 | c.46G>A p.G16R | Missense Mutation (SNP) | VAF 110/449 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.077); catalogued as COSV67587339; called by muse, mutect2, varscan2
- SLC16A7 | c.762T>G p.N254K | Missense Mutation (SNP) | VAF 94/242 reads (39%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.994); catalogued as COSV53898290; called by muse, mutect2, varscan2
- SLCO4C1 | c.1994C>T p.A665V | Missense Mutation (SNP) | VAF 71/185 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.688); catalogued as COSV60516073; called by muse, mutect2, varscan2
- SORT1 | c.2191C>T p.R731* | Nonsense Mutation (SNP) | VAF 85/221 reads (38%) | catalogued as COSV56668099, COSV56668162; called by muse, mutect2, varscan2
- TMEM117 | c.1349G>A p.R450Q | Missense Mutation (SNP) | VAF 130/315 reads (41%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.356); catalogued as rs200252296; called by muse, mutect2, varscan2
- TMEM201 | c.313C>T p.R105C | Missense Mutation (SNP) | VAF 170/421 reads (40%) | SIFT tolerated (0.3); PolyPhen benign (0.015); catalogued as rs967735686; called by muse, mutect2, varscan2
- TRAPPC8 | c.914C>T p.S305F | Missense Mutation (SNP) | VAF 100/415 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.068); catalogued as COSV51971101; called by muse, mutect2, varscan2
- UBTFL1 | c.629G>A p.R210Q | Missense Mutation (SNP) | VAF 86/230 reads (37%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs1281127300; called by muse, mutect2, varscan2
- UNC5C | c.806G>A p.W269* | Nonsense Mutation (SNP) | VAF 97/334 reads (29%) | catalogued as COSV71662922; called by muse, mutect2, varscan2
- UNC80 | c.9076G>C p.D3026H | Missense Mutation (SNP) | VAF 82/295 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.698); catalogued as rs1467565446; called by muse, mutect2, varscan2
- AMOT | c.1958C>T p.S653L (on ENST00000371959 / NM_001113490.1; = p.S244L on NM_133265.3) | Missense Mutation (SNP) | VAF 134/462 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- ARSF | c.344C>T p.P115L | Missense Mutation (SNP) | VAF 111/412 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- C2CD5 | c.2746C>T p.L916F | Missense Mutation (SNP) | VAF 28/233 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- CACNG6 | c.422C>T p.A141V | Missense Mutation (SNP) | VAF 104/255 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.639); called by muse, mutect2, varscan2
- CDH2 | c.2065C>T p.P689S | Missense Mutation (SNP) | VAF 110/439 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.54); called by muse, mutect2, varscan2
- CDR1 | c.337G>A p.E113K | Missense Mutation (SNP) | VAF 205/665 reads (31%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- COL6A2 | c.1204C>T p.P402S | Missense Mutation (SNP) | VAF 128/530 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- COL6A3 | c.4094C>T p.A1365V | Missense Mutation (SNP) | VAF 100/292 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.372); called by muse, mutect2, varscan2
- CSNKA2IP | c.1813C>T p.Q605* | Nonsense Mutation (SNP) | VAF 64/344 reads (19%) | called by muse, mutect2, varscan2
- DPP10 | c.428A>G p.Y143C | Missense Mutation (SNP) | VAF 48/153 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); called by muse, mutect2, varscan2
- ELMOD1 | c.98G>A p.G33E | Missense Mutation (SNP) | VAF 112/302 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- ERGIC1 | c.461C>T p.S154F | Missense Mutation (SNP) | VAF 114/276 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.214); called by muse, mutect2, varscan2
- ERVW-1 | c.1309C>T p.P437S | Missense Mutation (SNP) | VAF 132/369 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ETV6 | c.640C>T p.P214S | Missense Mutation (SNP) | VAF 208/548 reads (38%) | SIFT tolerated (0.35); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- F7 | c.248C>T p.S83F | Missense Mutation (SNP) | VAF 172/419 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- FAM186A | c.2882_2883insCCTCGGAG p.R961Sfs*18 | Frame Shift Ins (INS) | VAF 153/400 reads (38%) | called by mutect2, pindel, varscan2
- FAM98C | c.805C>T p.P269S | Missense Mutation (SNP) | VAF 121/348 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- FANCB | c.2244A>C p.K748N | Missense Mutation (SNP) | VAF 29/376 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); called by muse, mutect2
- FLRT2 | c.31C>T p.H11Y | Missense Mutation (SNP) | VAF 135/412 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FOCAD | c.3083C>T p.S1028F | Missense Mutation (SNP) | VAF 59/189 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FRAS1 | c.10048G>A p.G3350R | Missense Mutation (SNP) | VAF 114/399 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FRAS1 | c.10049G>A p.G3350E | Missense Mutation (SNP) | VAF 114/402 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FUCA2 | c.692G>A p.G231E | Missense Mutation (SNP) | VAF 104/422 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.178); called by muse, mutect2
- GET1-SH3BGR | c.703G>A p.E235K | Missense Mutation (SNP) | VAF 83/408 reads (20%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GGT7 | c.697C>T p.P233S | Missense Mutation (SNP) | VAF 129/349 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- HS3ST2 | c.223C>T p.P75S | Missense Mutation (SNP) | VAF 230/525 reads (44%) | SIFT tolerated (0.82); PolyPhen benign (0); called by muse, mutect2, varscan2
- HTR3C | c.598G>A p.E200K | Missense Mutation (SNP) | VAF 126/296 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.673); called by muse, mutect2, varscan2
- IL17B | c.178G>A p.E60K | Missense Mutation (SNP) | VAF 117/281 reads (42%) | SIFT tolerated (0.29); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- KCNN1 | c.647C>G p.T216R | Missense Mutation (SNP) | VAF 244/561 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- KIF21A | c.3016T>G p.C1006G (on ENST00000361418 / NM_001378440.1; = p.C993G on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 103/280 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- KRT1 | c.1931G>C p.R644T | Missense Mutation (SNP) | VAF 62/258 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KRT10 | c.287G>A p.G96E | Missense Mutation (SNP) | VAF 227/824 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- LAMA2 | c.1691C>T p.P564L | Missense Mutation (SNP) | VAF 160/512 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- LZTR1 | c.667G>T p.E223* | Nonsense Mutation (SNP) | VAF 113/279 reads (41%) | called by muse, mutect2, varscan2
- MUC17 | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 107/325 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- NACA2 | c.628A>G p.I210V | Missense Mutation (SNP) | VAF 91/383 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- NRIP1 | c.1949C>T p.P650L | Missense Mutation (SNP) | VAF 81/399 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PITX2 | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 116/397 reads (29%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- PLBD1 | c.1352A>T p.K451I | Missense Mutation (SNP) | VAF 109/236 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PLG | c.317G>A p.G106E | Missense Mutation (SNP) | VAF 58/276 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- PLS3 | c.1404A>T p.E468D | Missense Mutation (SNP) | VAF 76/306 reads (25%) | SIFT tolerated (0.33); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PRPF8 | c.2573A>C p.Q858P | Missense Mutation (SNP) | VAF 131/431 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.544); called by muse, mutect2, varscan2
- PTPRZ1 | c.2305C>T p.P769S | Missense Mutation (SNP) | VAF 167/418 reads (40%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.782); called by muse, mutect2, varscan2
- ROR2 | c.2368A>C p.K790Q | Missense Mutation (SNP) | VAF 141/363 reads (39%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SERPINA9 | c.13C>T p.L5F | Missense Mutation (SNP) | VAF 104/387 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SERPINB13 | c.1021G>A p.E341K | Missense Mutation (SNP) | VAF 147/521 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.519); called by muse, mutect2, varscan2
- SEZ6L | c.260G>T p.G87V | Missense Mutation (SNP) | VAF 70/481 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.526); called by muse, mutect2, varscan2
- SFTPA1 | c.98C>T p.P33L | Missense Mutation (SNP) | VAF 47/462 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SFTPA2 | c.98C>T p.P33L | Missense Mutation (SNP) | VAF 109/371 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SGK2 | c.193C>T p.P65S | Missense Mutation (SNP) | VAF 109/298 reads (37%) | SIFT tolerated (0.26); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SH3D19 | c.85C>T p.R29C | Missense Mutation (SNP) | VAF 140/465 reads (30%) | SIFT deleterious, low confidence (0); called by muse, mutect2, varscan2
- SIMC1 | c.918delinsGGTTTGGGGG p.S306_P307insVWG (on ENST00000443967 / NM_001308196.1; = p.S325_P326insVWG on NM_001308195.2) | In Frame Ins (INS) | VAF 87/483 reads (18%) | called by pindel, varscan2*
- SLC22A1 | c.929G>A p.G310E | Missense Mutation (SNP) | VAF 102/382 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- SLIT2 | c.2144-1G>A p.X715_splice | Splice Site (SNP) | VAF 74/236 reads (31%) | called by muse, mutect2, varscan2
- SMAD9 | c.68G>A p.G23D | Missense Mutation (SNP) | VAF 111/295 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- SMAD9 | c.67G>A p.G23S | Missense Mutation (SNP) | VAF 111/298 reads (37%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.801); called by muse, mutect2, varscan2
- SRPX | c.949T>G p.C317G | Missense Mutation (SNP) | VAF 110/424 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SULT1C3 | c.151C>A p.L51M | Missense Mutation (SNP) | VAF 58/181 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); called by muse, mutect2, varscan2
- TACR1 | c.971C>T p.P324L | Missense Mutation (SNP) | VAF 105/263 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- TOPBP1 | c.2962C>T p.L988F | Missense Mutation (SNP) | VAF 81/235 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TUBE1 | c.1157C>T p.S386F | Missense Mutation (SNP) | VAF 116/396 reads (29%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- USP26 | c.2368G>T p.A790S | Missense Mutation (SNP) | VAF 151/489 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.401); called by muse, mutect2, varscan2
- WASHC4 | c.843_844insGGGG p.S282Gfs*6 | Frame Shift Ins (INS) | VAF 87/242 reads (36%) | called by mutect2, pindel*, varscan2*
- XYLB | c.1553C>T p.P518L | Missense Mutation (SNP) | VAF 98/265 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZBTB7A | c.785C>T p.A262V | Missense Mutation (SNP) | VAF 166/508 reads (33%) | SIFT tolerated (0.97); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADAM9 | c.81C>T p.L27= | Silent (SNP) | VAF 77/350 reads (22%) | catalogued as rs530146456, COSV65963122; called by muse, mutect2, varscan2
- ADGRV1 | c.18546C>T p.F6182= | Silent (SNP) | VAF 138/312 reads (44%) | catalogued as COSV101316657; called by muse, mutect2, varscan2
- ARHGEF38 | c.864G>A p.R288= | Silent (SNP) | VAF 63/196 reads (32%) | called by muse, mutect2, varscan2
- BTBD2 | c.735C>T p.I245= | Silent (SNP) | VAF 110/281 reads (39%) | catalogued as rs758890370, COSV55308228; called by muse, mutect2, varscan2
- CATSPERB | c.321G>C p.R107= | Silent (SNP) | VAF 84/386 reads (22%) | called by muse, mutect2, varscan2
- CCDC141 | c.240G>A p.R80= | Silent (SNP) | VAF 55/162 reads (34%) | catalogued as COSV69456641; called by muse, mutect2, varscan2
- CDYL2 | c.1203C>T p.I401= | Silent (SNP) | VAF 54/272 reads (20%) | catalogued as COSV73655141; called by muse, mutect2, varscan2
- CFAP61 | c.1755C>T p.S585= | Silent (SNP) | VAF 101/251 reads (40%) | catalogued as rs773163898; called by muse, mutect2, varscan2
- CGRRF1 | c.687C>T p.F229= | Silent (SNP) | VAF 61/214 reads (29%) | catalogued as rs1209412437, COSV53596842; called by muse, mutect2, varscan2
- CHI3L2 | c.519C>T p.S173= | Silent (SNP) | VAF 48/166 reads (29%) | catalogued as rs1311615375; called by muse, mutect2, varscan2
- CHRNB2 | c.1011C>T p.V337= | Silent (SNP) | VAF 159/433 reads (37%) | catalogued as rs766422414; called by muse, mutect2, varscan2
- COBL | c.1833C>T p.I611= | Silent (SNP) | VAF 132/326 reads (40%) | catalogued as COSV104371510; called by muse, mutect2, varscan2
- COL24A1 | c.3510G>A p.G1170= | Silent (SNP) | VAF 87/222 reads (39%) | called by muse, mutect2, varscan2
- COL6A3 | c.4095C>T p.A1365= | Silent (SNP) | VAF 101/294 reads (34%) | called by muse, mutect2, varscan2
- DDR2 | c.372G>A p.R124= | Silent (SNP) | VAF 126/336 reads (38%) | called by muse, mutect2, varscan2
- DGKK | c.1581T>G p.G527= | Silent (SNP) | VAF 111/323 reads (34%) | called by muse, mutect2, varscan2
- DLGAP2 | c.1002C>T p.P334= | Silent (SNP) | VAF 270/650 reads (42%) | catalogued as rs758951779, COSV70102797; called by muse, mutect2, varscan2
- DMBT1 | c.6234C>T p.T2078= (on ENST00000338354 / NM_001377530.1; = p.T1321= on NM_004406.3) | Silent (SNP) | VAF 115/265 reads (43%) | called by muse, mutect2, varscan2
- DMD | c.8094G>A p.L2698= | Silent (SNP) | VAF 139/510 reads (27%) | called by muse, mutect2, varscan2
- DPYSL2 | c.9G>A p.E3= | Silent (SNP) | VAF 58/158 reads (37%) | called by muse, varscan2
- ENO4 | c.1032G>A p.G344= (on ENST00000622726; = p.G341= on NM_001242699.2) | Silent (SNP) | VAF 94/276 reads (34%) | catalogued as rs1051215086; called by muse, mutect2, varscan2
- F7 | c.249C>T p.S83= | Silent (SNP) | VAF 171/413 reads (41%) | catalogued as COSV60646220; called by muse, mutect2, varscan2
- FDXACB1 | c.1722C>T p.S574= | Silent (SNP) | VAF 122/340 reads (36%) | catalogued as rs1555161846; called by muse, varscan2
- FHDC1 | c.2772C>T p.S924= | Silent (SNP) | VAF 193/649 reads (30%) | called by muse, mutect2, varscan2
- GOLGA8S | c.183C>T p.I61= | Silent (SNP) | VAF 14/26 reads (54%) | called by mutect2, varscan2
- GRID2 | c.846G>A p.T282= | Silent (SNP) | VAF 119/434 reads (27%) | catalogued as rs773668647, COSV56168084; called by muse, mutect2, varscan2
- GRIK2 | c.1014C>T p.P338= | Silent (SNP) | VAF 112/418 reads (27%) | called by muse, mutect2, varscan2
- HLCS | c.1434G>A p.T478= | Silent (SNP) | VAF 180/394 reads (46%) | catalogued as rs776800808; ClinVar: likely benign; called by muse, mutect2, varscan2
- IQCH | c.1530C>T p.I510= | Silent (SNP) | VAF 116/320 reads (36%) | catalogued as COSV60056247; called by muse, mutect2, varscan2
- LRRC53 | c.1053G>A p.K351= | Silent (SNP) | VAF 90/280 reads (32%) | catalogued as COSV53949578; called by muse, mutect2, varscan2
- MUC16 | c.14958G>A p.Q4986= | Silent (SNP) | VAF 137/314 reads (44%) | catalogued as COSV67462131; called by muse, mutect2, varscan2
- NHSL1 | c.1515C>T p.V505= | Silent (SNP) | VAF 136/503 reads (27%) | called by muse, mutect2, varscan2
- NMT1 | c.603C>T p.L201= | Silent (SNP) | VAF 100/303 reads (33%) | called by muse, mutect2, varscan2
- NRIP1 | c.1950C>T p.P650= | Silent (SNP) | VAF 79/398 reads (20%) | called by muse, mutect2, varscan2
- PLG | c.318G>A p.G106= | Silent (SNP) | VAF 57/275 reads (21%) | catalogued as rs747756137; called by muse, mutect2, varscan2
- PPP1R3F | c.2400G>A p.*800= | Silent (SNP) | VAF 128/400 reads (32%) | called by muse, mutect2, varscan2
- SERPINA9 | c.12C>T p.Y4= | Silent (SNP) | VAF 104/386 reads (27%) | called by muse, mutect2, varscan2
- SLC6A13 | c.1764C>T p.P588= | Silent (SNP) | VAF 116/277 reads (42%) | catalogued as rs1220855685; called by muse, mutect2, varscan2
- SLC6A6 | c.423C>T p.I141= | Silent (SNP) | VAF 100/293 reads (34%) | called by muse, mutect2, varscan2
- SUSD4 | c.1134C>T p.S378= | Silent (SNP) | VAF 217/482 reads (45%) | called by muse, mutect2, varscan2
- TRPV3 | c.456G>A p.E152= | Silent (SNP) | VAF 100/377 reads (27%) | called by muse, mutect2, varscan2
- UNC5C | c.606G>A p.L202= | Silent (SNP) | VAF 52/205 reads (25%) | called by muse, mutect2, varscan2
- ZBTB7A | c.786C>T p.A262= | Silent (SNP) | VAF 164/506 reads (32%) | called by muse, mutect2, varscan2
- AL353804.7 | chrX:73850195 G>A | 5'Flank (SNP) | VAF 97/318 reads (31%) | called by muse, mutect2, varscan2
- B4GALNT1 | c.712+151G>A | Intron (SNP) | VAF 184/430 reads (43%) | called by muse, mutect2, varscan2
- CDH8 | c.*5744G>A | 3'UTR (SNP) | VAF 67/178 reads (38%) | called by muse, mutect2, varscan2
- CDH8 | c.*5743G>A | 3'UTR (SNP) | VAF 67/178 reads (38%) | called by muse, mutect2, varscan2
- GNAO1 | c.723+4118G>A | Intron (SNP) | VAF 76/210 reads (36%) | called by muse, mutect2, varscan2
- KANSL1L | c.2029+79A>T | Intron (SNP) | VAF 56/130 reads (43%) | called by muse, mutect2, varscan2
- MLIP | c.612+11914C>T | Intron (SNP) | VAF 98/371 reads (26%) | catalogued as rs1398933414; called by muse, mutect2, varscan2
- NBR1 | c.*546C>T | 3'UTR (SNP) | VAF 91/333 reads (27%) | called by muse, mutect2, varscan2
- RN7SL495P | chr15:22607827 C>T | 3'Flank (SNP) | VAF 131/518 reads (25%) | called by muse, varscan2
- RN7SL495P | chr15:22607828 C>T | 3'Flank (SNP) | VAF 130/516 reads (25%) | called by muse, varscan2
- SLC5A10 | c.1242-2091C>T | Intron (SNP) | VAF 116/413 reads (28%) | called by muse, mutect2, varscan2
- SNX13 | c.-169G>A | 5'UTR (SNP) | VAF 143/339 reads (42%) | called by muse, mutect2, varscan2
- SREK1 | c.-291C>T | 5'UTR (SNP) | VAF 100/267 reads (37%) | catalogued as COSV99398838; called by muse, mutect2, varscan2
